Somatic mutation profile of tumor specimen TCGA-DX-A3UE-01A (aliquot TCGA-DX-A3UE-01A-11D-A307-09) from TCGA case TCGA-DX-A3UE, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 66.8 years (24,388 days).
Specimen TCGA-DX-A3UE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04340efe-9ba6-487d-b588-b0481d75e770.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3UE-10A (Blood Derived Normal), aliquot TCGA-DX-A3UE-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/947dde64-013e-4a8e-8382-b46aba52ddcb

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, 3'UTR 2, Nonsense Mutation 2, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.784_786del p.G262del | In Frame Del (DEL) | VAF 13/17 reads (76%) | hotspot (GDC flag); catalogued as rs1567548347; ClinVar: uncertain significance; called by mutect2, varscan2
- AARS2 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as rs1333355984, COSV99771241; called by muse, mutect2, varscan2
- ACSL4 | c.1612G>C p.A538P (on ENST00000340800 / NM_022977.2; = p.A497P on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as COSV100538285; called by muse, mutect2
- ADARB2 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs369823256; called by muse, mutect2, varscan2
- AKAP13 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100773164; called by muse, mutect2, varscan2
- ALDH18A1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs754880517, COSV64663356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTK | c.775G>C p.G259R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100437316, COSV58119675; called by muse, mutect2, varscan2
- CACNG3 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs555623613, COSV50066446; called by muse, varscan2
- CDH7 | c.1028C>A p.A343D | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100541461; called by muse, mutect2, varscan2
- CES3 | c.758C>A p.T253K | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs750607823, COSV100309804; called by muse, mutect2, varscan2
- CRB1 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77334581, COSV66330890; called by muse, mutect2, varscan2
- CRNN | c.1169T>A p.V390E | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99663928; called by muse, mutect2, varscan2
- FGFBP1 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.14); PolyPhen benign (0.316); catalogued as COSV99468925; called by muse, mutect2, varscan2
- HIRA | c.603G>C p.W201C | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99599924; called by muse, mutect2
- MYF6 | c.536T>A p.F179Y | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as COSV99952662; called by muse, mutect2, varscan2
- MYH4 | c.3647G>A p.R1216Q | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs766999823, COSV99700374, COSV99701442; called by muse, mutect2, varscan2
- NCOR2 | c.3931T>A p.Y1311N | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100656881; called by muse, mutect2, varscan2
- NGF | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101049340; called by muse, mutect2, varscan2
- OR9Q1 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100109381; called by muse, mutect2
- OTOL1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100019751; called by muse, mutect2, varscan2
- P2RX7 | c.635T>A p.L212* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99947428; called by muse, mutect2
- PAM | c.970G>C p.V324L | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV99173056; called by muse, mutect2
- PCNX2 | c.5911A>G p.T1971A | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as COSV99266097; called by muse, mutect2, varscan2
- RAB9B | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99685978; called by muse, mutect2, varscan2
- RPA4 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100230867; called by muse, mutect2, varscan2
- SLC15A1 | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV100919421; called by muse, mutect2, varscan2
- SLC30A9 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100047969; called by muse, mutect2
- SLC39A6 | c.1731T>G p.S577R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV99309355; called by muse, mutect2, varscan2
- SLC9A9 | c.862A>G p.M288V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1272399153, COSV100339463; called by muse, mutect2, varscan2
- SNAPC4 | c.2396A>G p.H799R | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100046820; called by muse, mutect2, varscan2
- SPATA31D1 | c.3470C>T p.T1157I | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV100782478; called by muse, mutect2, varscan2
- TBPL2 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV99905290; called by muse, mutect2
- TGIF1 | c.304T>C p.S102P (on ENST00000330513 / NM_001374396.1; = p.S122P on NM_003244.4) | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV100394719; called by muse, mutect2, varscan2
- THOC2 | c.3685A>C p.K1229Q | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV99832763; called by muse, mutect2, varscan2
- TMTC1 | c.2209G>A p.E737K (on ENST00000539277 / NM_001193451.2; = p.E629K on NM_175861.3) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV99758793; called by muse, mutect2, varscan2
- UBA2 | c.1338C>G p.S446R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV99875338; called by muse, mutect2, varscan2
- VIPR1 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100285487; called by muse, mutect2, varscan2
- ZNF564 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV59434766; called by muse, mutect2, varscan2
- ZNF786 | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs926337235, COSV100302670; called by muse, mutect2, varscan2
- BRD2 | c.733G>T p.V245F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2
- RB1 | c.1868dup p.N623Kfs*30 | Frame Shift Ins (INS) | VAF 27/42 reads (64%) | called by mutect2, pindel, varscan2
- RPS6KC1 | c.1958A>T p.E653V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- ACSL6 | c.1419C>T p.G473= (on ENST00000379240; = p.G498= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs138919958; called by muse, mutect2, varscan2
- ADRB2 | c.132C>T p.V44= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs752474318, COSV100019095; called by muse, mutect2, varscan2
- ANAPC2 | c.1927C>T p.L643= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV100118895; called by muse, mutect2, varscan2
- CACNA1A | c.3462C>T p.S1154= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs751700486, COSV64205308; called by muse, mutect2, varscan2
- COL6A6 | c.5166A>G p.G1722= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100649823; called by muse, mutect2
- CUBN | c.10419G>A p.L3473= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1468810944, COSV100912073; called by muse, mutect2, varscan2
- DOCK4 | c.5700G>T p.P1900= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV70233624, COSV70235053; called by muse, mutect2, varscan2
- FAM47C | c.2316C>A p.S772= | Silent (SNP) | VAF 174/329 reads (53%) | catalogued as COSV63726949; called by muse, mutect2, varscan2
- FLG2 | c.216T>G p.T72= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV101165600; called by muse, mutect2, varscan2
- GDF11 | c.1026C>T p.S342= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs200313464, COSV99143963; called by muse, varscan2
- MAP1A | c.1596A>T p.T532= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100288104; called by muse, mutect2
- MLIP | c.156C>G p.T52= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99228490; called by muse, mutect2, varscan2
- PLIN2 | c.1206A>G p.V402= | Silent (SNP) | VAF 65/139 reads (47%) | catalogued as COSV99438712; called by muse, mutect2, varscan2
- PNPLA7 | c.2265C>T p.S755= | Silent (SNP) | VAF 90/194 reads (46%) | catalogued as rs756565279, COSV99480132; called by muse, mutect2, varscan2
- PPP5C | c.1206G>A p.V402= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV99180841; called by muse, mutect2, varscan2
- SEMA6C | c.2181C>T p.N727= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV58999809; called by muse, mutect2
- TUBA4A | c.177A>G p.G59= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV99944613; called by muse, mutect2, varscan2
- UGT1A5 | c.780C>T p.D260= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as rs780343524, COSV100529568; called by muse, mutect2
- BAZ1A | c.*2T>A | 3'UTR (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100701089; called by muse, mutect2
- CLLU1 | chr12:92422612 C>G | 5'Flank (SNP) | VAF 28/59 reads (47%) | catalogued as COSV101029170; called by muse, mutect2, varscan2
- MIR525 | n.73G>A | RNA (SNP) | VAF 56/113 reads (50%) | catalogued as rs760774308; called by muse, mutect2, varscan2
- SPARCL1 | c.*2C>T | 3'UTR (SNP) | VAF 18/30 reads (60%) | catalogued as rs770032343, COSV99215291; called by muse, varscan2
